Somatic mutation profile of tumor specimen 0DUHI7 from CCDI case PBCLGH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.3 years (823 days).
Specimen 0DUHI7: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04ef1fe4-8ae4-4940-8495-72a69179b755.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUHJ3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/abbadc17-7659-42d5-aad7-f91eb7845fd4

The open-access MAF lists 30 somatic variants for this specimen: 23 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 4, Intron 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.16640G>A p.R5547H | Missense Mutation (SNP) | VAF 99/534 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs200907244; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTBD9 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 105/582 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs150015110, COSV58426603; called by muse, mutect2, varscan2
- CHEK1 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 38/468 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs761313560, COSV54022462; called by muse, mutect2
- COL22A1 | c.1747G>T p.V583F | Missense Mutation (SNP) | VAF 84/339 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.424); catalogued as COSV57364099; called by muse, mutect2, varscan2
- DDX51 | c.1700G>A p.R567Q | Missense Mutation (SNP) | VAF 44/309 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57958951; called by muse, mutect2, varscan2
- F7 | c.1324C>A p.Q442K | Missense Mutation (SNP) | VAF 126/528 reads (24%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as CM073034; called by muse, mutect2, varscan2
- JPH3 | c.1687C>T p.R563C | Missense Mutation (SNP) | VAF 88/338 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs771342408; called by muse, mutect2, varscan2
- LEF1 | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 175/387 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs142779919; called by muse, mutect2, varscan2
- ARAP2 | c.1287T>A p.N429K | Missense Mutation (SNP) | VAF 50/760 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.084); called by muse, mutect2
- BICRAL | c.1312G>T p.A438S | Missense Mutation (SNP) | VAF 209/476 reads (44%) | SIFT tolerated (0.83); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CHSY3 | c.1384G>T p.E462* | Nonsense Mutation (SNP) | VAF 116/538 reads (22%) | called by muse, mutect2, varscan2
- CRYBG3 | c.2217T>G p.S739R | Missense Mutation (SNP) | VAF 169/655 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CSF1R | c.1969G>T p.G657C | Missense Mutation (SNP) | VAF 49/369 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FLT3 | c.847C>A p.L283I | Missense Mutation (SNP) | VAF 86/502 reads (17%) | SIFT tolerated (0.92); PolyPhen benign (0.165); called by mutect2, varscan2
- MAGEC1 | c.1151C>A p.T384N | Missense Mutation (SNP) | VAF 250/622 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.485); called by mutect2, varscan2
- MTERF4 | c.55T>G p.W19G | Missense Mutation (SNP) | VAF 16/524 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2
- NAA25 | c.1828G>T p.A610S | Missense Mutation (SNP) | VAF 26/594 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.806); called by muse, mutect2
- NEK9 | c.2428G>T p.G810C | Missense Mutation (SNP) | VAF 75/261 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- OR2G2 | c.673G>T p.A225S | Missense Mutation (SNP) | VAF 61/379 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.411); called by muse, varscan2
- OR5T2 | c.278A>T p.Q93L | Missense Mutation (SNP) | VAF 86/573 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- PCDHGA10 | c.2090T>G p.L697R | Missense Mutation (SNP) | VAF 117/655 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- SPATC1L | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 17/522 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.229); called by muse, mutect2
- TTN | c.88267C>A p.Q29423K (on ENST00000591111; = p.Q21999K on NM_003319.4) | Missense Mutation (SNP) | VAF 78/430 reads (18%) | PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- ABCA4 | c.4365T>C p.C1455= | Silent (SNP) | VAF 226/488 reads (46%) | called by muse, mutect2, varscan2
- FLT3 | c.846G>A p.G282= | Silent (SNP) | VAF 95/544 reads (17%) | called by muse, mutect2, varscan2
- NOMO3 | c.156T>G p.S52= | Silent (SNP) | VAF 25/213 reads (12%) | catalogued as rs1344150753; called by muse, mutect2, varscan2
- ZXDB | c.1044G>T p.V348= | Silent (SNP) | VAF 165/447 reads (37%) | called by muse, mutect2, varscan2
- ATP7B | c.2122-17C>T | Intron (SNP) | VAF 31/185 reads (17%) | called by muse, mutect2, varscan2
- CIR1 | c.167+90G>T | Intron (SNP) | VAF 18/115 reads (16%) | catalogued as rs1482192868; called by muse, mutect2, varscan2
- PDE6A | c.1473+58_1473+79del | Intron (DEL) | VAF 102/239 reads (43%) | called by mutect2, pindel, varscan2
